Gene-level copy-number profile of tumor specimen TCGA-C5-A3HD-01B from TCGA case TCGA-C5-A3HD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.2 years (18,690 days).
Specimen TCGA-C5-A3HD-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.286ec507-644f-47f2-bfa2-144b2715ff54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A3HD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a0bee32-6c4b-4bd6-948d-b74c7891657c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 10,444; copy number 2: 41,940; copy number 3: 6,118; copy number 4: 594; copy number 5: 703; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A3HD-01B-11D-A20T-01): tumor purity 0.91, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:65,843,890–66,009,200, 5 genes: RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 706 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:170,222,424–171,810,950, 29 genes, copy number 5 (within-gene range 3–5): PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1.
- chr12:39,058,028–39,619,803, 9 genes, copy number 5: AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3.
- chr15:71,792,638–95,327,129, 665 genes, copy number 5 (broad region; genes not listed).
- chr18:8,688,022–8,707,621, 2 genes, copy number 6: TOMM20P3, GACAT2.
- chr18:8,720,034–8,720,132, 1 gene, copy number 6: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 10,444. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
